Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-A4CG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-A4CG-01A (Primary Tumor).

[page 1 of 7]
Department of Pathology

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]
Service: Otolaryngology
Visit #: [REDACTED]
Location:
Facility:
Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

Surgical Pathology Consultation Report

ICD-0-3

* Addended *

carcinoma, squamous cell, NOS

8070/3

Site: buccal mucosa c 06.0

SPECIMEN(S) RECEIVED

1. Nck: Left neck - level 1B
2. Neck: Left neck level IIA
3. Thyroid: Possible pyramidal lobe of thyroid
4. Oral Cavity: Left cheek deep margin,
5. Oral Cavity: Lateral lip margin,
6. Oral Cavity: Palatal margin,
7. Oral Cavity: Posterior cheek margin
8. Oral Cavity: Left partial maxillectomy and left cheek
9. Neck: Left neck level I to IV

fw
9/24/12

DIAGNOSIS

1. Left neck; level IB:
- One lymph node, negative for malignancy (0/1).
2. Left neck; level IIA:
- One lymph node, negative for malignancy (0/1).
3. "Possible pyramidal lobe of thyroid":
- Thyroid tissue, negative for malignancy.
4. Left cheek deep margin:
- Negative for malignancy.
5. Lateral lip margin:
- Negative for malignancy.
6. Palatal margin:
- Negative for malignancy.
7. Posterior cheek margin:
- Negative for malignancy.
8. Left partial maxillectomy and left cheek:

[page 2 of 7]
- Squamous cell carcinoma, moderately differentiated.

Status: supplemental

Page: 1 of 6

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Resulted: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

- a. The tumour involves the buccal mucosa.
- b. Maximum tumour dimension 4.5 cm.
- c. Maximum tumour thickness 0.7 cm.
- d. Positive for perineural invasion.
- e. Negative for lymphovascular invasion.
- f. Tumour is very close (< 0.1 cm) to anterior buccal as well as inferior and posterior buccal (0.3 cm) margins.
- g. Bone and bone margins are pending decalcification and will be reported in an addendum.

9. Left neck; level I to IV:

- Fourteen lymph nodes, negative for malignancy (0/14).
- Submandibular gland, negative for malignancy.

COMMENT

The T-stage in the synoptic report is deferred pending bone sections.

SYNOPTIC DATA

Specimen:	Buccal mucosa (inner cheek)
Received:	Fresh
Procedure:	Maxillectomy: Left partial
maxillectomy and left cheek	
Specimen Size:	Greatest dimension: 5.2 cm
	Additional dimension: 4.0 cm
	Additional dimension: 2.5 cm
	Left
Specimen Laterality:	Buccal mucosa (inner cheek)
Tumor Site:	Single focus
Tumor Focality:	Greatest dimension: 4.5 cm
Tumor Size:	Additional dimension: 3.9 cm
	Additional dimension: 0.7 cm
Histologic Type:	Squamous cell carcinoma, conventional

[page 3 of 7]
Histologic Grade:
Margins:
carcinoma

cm

G2: Moderately differentiated
Margins uninvolved by invasive

Distance from closest margin: 0.08

Margin(s): Anterior buccal margin.
Margins uninvolved by carcinoma in

Status: supplemental

Page: 2 of 6

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location:

Facility:

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

situ (includes moderate and severe dysplasia)

Distance from closest margin: 0.7 cm

Lymph-Vascular Invasion:

Perineural Invasion:

Lymph Nodes, Extranodal Extension:

TNM Descriptors:

Primary Tumor (pT):

Regional Lymph Nodes (pN):
metastasis

Margin(s): Anterior margin of lip.

Not identified

Present

Not identified

Not applicable

pTX: Cannot be assessed

pN0: No regional lymph node

examined: 16

Number of regional lymph nodes

involved: 0

Number of regional lymph nodes

Distant Metastasis (pM):

Not applicable

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

ELECTRONICALLY VERIFIED BY.

CLINICAL HISTORY

cancer left buccal cavity

[page 4 of 7]
GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "left neck, level 1B", contains a tan fatty tissue fragment measuring 1.8 x 1.4 x 0.6 cm which is received in 10% neutral buffered formalin.

1A -- specimen bisected and submitted in toto

2. The specimen container labeled with the patient's name and as "left neck, level 2A", contains two tan fatty tissue fragments measuring 0.5 x 0.4 x 0.4-cm and 0.8 x 0.4 x 0.4 cm received in 10% neutral buffered formalin.

2A -- specimen submitted in toto

Status: supplemental

Page: 3 of 6

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location:

Facility:

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

3. The specimen container labeled with the patient's name and as "possible pyramidal lobe of thyroid", contains a tan tiny tissue fragment measuring 1.9 x 0.6 x 0.4-cm which is received in 10% neutral buffered formalin.

3A -- specimen submitted in toto.

4. The specimen container labeled with the patient's name and as "left cheek deep margin", contains a single tan tissue fragment measuring 2.5 x 0.5 x 0.5 cm which is received fresh. The specimen is submitted for quick section and further submitted for permanent processing.

4A -- specimen submitted in toto.

5. The specimen container labeled with the patient's name and as "lateral lip margin", contains a single tan tissue fragment measuring 0.5 x 0.4 x 0.4-cm which is received fresh. The specimen is submitted for quick section and further submitted for permanent processing.

5A -- specimen submitted in toto.

6. The specimen container labeled with the patient's name and as "palatal margin", contains a tan tissue fragment measuring 2.0 x 0.6 x 0.3 cm which is received fresh. The specimen is submitted for quick section and further submitted for permanent processing.

[page 5 of 7]
6A -- specimen submitted in toto.

7. The specimen container labeled with the patient's name and as "posterior cheek margin", contains a tan tissue fragment which is 0.7 x 0.6 x 0.3 cm which is received fresh. The specimen is submitted for quick section further submitted for permanent processing.

7A -- specimen submitted in toto.

8. The specimen is labeled with the patient's name and as "left partial maxillectomy and left cheek". It consists of a left partial maxillectomy and left cheek measuring 5.2 AP X 4.0 cm SI X 2.5 cm ML. It includes a portion of maxillary bone and medial maxillary sinus with no teeth measuring 0.8 cm SI x 2.1 cm ML x 4.0cm AP. There is a fragment of lip on the anterior margin measuring 1.5 cm SI x 1.0 cm ML x 1.5 cm AP. The maxillary sinus measures 2.0 x 1.0 cm. There is a tan nodular tumor arising in the buccal mucosa extending to the junction of the buccal and gingival mucosa. The tumor measures 4.5 AP x 3.9 SI x 0.7 ML cm. The tumor is tan nodular and slightly friable. There is no grossly obvious involvement of bone by the tumour. The tumor is located at 0.2 cm from

Status: supplemental

Page: 4 of 6

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

the closest deep soft tissue margin of the buccal mucosa. Remaining margins are as follows: Anterior buccal margin 0.5-cm, posterior buccal margin 0.4-cm, inferior buccal margin 0.3 cm, superior gingival margin 1.0-cm, anterior lip margin 1.4-cm. The excision margin is painted with Silver nitrate. The specimen is sketched on the requisition. Tissue is submitted frozen. Representative sections are submitted.

8A -- anterior buccal margin with lesion

8B -- inferior buccal margin with lesion

8C -- posterior buccal margin with lesion

8D -- superior gingival margin with lesion

8E -- anterior margin of lip with lesion

8F -- en face excision margin of maxillary sinus following decalcification

8G 8H -- en face excision margin of maxillary bone following decalcification

8I -- section of mass with maxillary bone following decalcification.

[page 6 of 7]
9. The specimen is labeled with the patient's name and as "left neck level 1 to 4". It consists of a portion of fibroadipose tissue measuring 12-cm SI x 6.5 cm AP x 2.0 cm is received in 10% neutral buffered formalin. Orientation is grossly obvious.

Level 1 reveals the presence of a submandibular gland measuring 3.0 x 3.0 x 1.5 cm which has an unremarkable external and cut surface as well as 3 tan fatty lymph nodes measuring from 1.0 x 0.6 x 0.5cm up to 2.0 x 1.0 x 0.8 cm which have a tan fatty cut surface.

9A -- section of submandibular gland

9B --9D -- a single lymph node bisected in each block

Level 2 reveals a single tan lymph node measuring 0.7 x 0.5 to 0.4 cm.

9E -- a single lymph node.

Level 3 reveals the presence of 5 tan lymph nodes measuring from 0.5 x 0.4 x 0.3cm up to 2.5 x 1.2 x 1.0cm, sectioning reveals a tan fatty cut surface.

9F -- 9 I -- a single lymph node bisected in each block

9J -- a single lymph node

Level 4 reveals the presence of 5 tan lymph nodes measuring 0.6 x 0.2 x 0.3cm up to 1.5 x 1.0 x 0.5-cm, sectioning reveals a tan fatty cut surface

Status: supplemental

Page: 5 of 6

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location:

Facility:

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

9K --9L -- a single lymph node bisected in each block

9M -- multiple individual lymph nodes.

QUICK SECTION

4. Negative for carcinoma

5. Negative for carcinoma. Focal dysplasia present.

6. Negative for carcinoma

[page 7 of 7]
7. Negative for carcinoma

Reported to

Addendum Status: Signed Out
Date Reported:

Addendum Diagnosis

8. Left partial maxillectomy (bone sections):

- There is no invasion of bone or involvement of the bone margins.

Addendum Comment

The tumour is a pT3 based on tumour size and lack of bone invasion.

Status: supplemental

Page: 6 of 6

8/23/12

Source: NCI Genomic Data Commons file 49f5815e-d9ca-4bd3-857a-c2901929cabc (TCGA-CQ-A4CG.BAB451BB-7156-42C9-9CF1-39C8BE6E2BD7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).